Somatic mutation profile of tumor specimen TCGA-R5-A7ZE-01B (aliquot TCGA-R5-A7ZE-01B-11D-A34U-08) from TCGA case TCGA-R5-A7ZE, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 66.6 years (24,328 days).
Specimen TCGA-R5-A7ZE-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3fe1fc0-d1b1-4b6d-b327-4d87d3cf0e4f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-R5-A7ZE-10A (Blood Derived Normal), aliquot TCGA-R5-A7ZE-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cf3ad78e-9ca1-4e4a-93e4-de5c5e4e5512

The open-access MAF lists 160 somatic variants for this specimen: 122 protein-altering or splice-affecting, 36 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 108, Silent 36, Nonsense Mutation 7, Frame Shift Del 3, RNA 2, Splice Site 2, In Frame Ins 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SDHA | c.778G>A p.G260R | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs940845256, COSV99372355; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.517G>T p.V173L | Missense Mutation (SNP) | VAF 48/94 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A2M | c.419C>A p.P140Q | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100589122; called by muse, mutect2
- ABCA12 | c.5848C>T p.R1950* (on ENST00000272895 / NM_173076.3; = p.R1632* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 27/65 reads (42%) | catalogued as rs375437551, CM052165; called by muse, mutect2, varscan2
- ADAMTS20 | c.265T>A p.F89I | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101240768; called by muse, mutect2, varscan2
- AGR3 | c.321G>T p.K107N | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100124073, COSV60037880; called by muse, mutect2
- AKAP13 | c.875A>G p.K292R | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV100774931; called by muse, mutect2, varscan2
- ARHGAP35 | c.1141G>T p.V381F | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as COSV68332596; called by muse, mutect2
- ARMC4 | c.2980G>A p.A994T | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs369022423, COSV100537518; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASB5 | c.581T>G p.V194G | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV56674543, COSV99642265; called by muse, mutect2
- ATP1A2 | c.2354C>T p.T785I | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.912); catalogued as rs757260843, COSV100768251; called by muse, mutect2, varscan2
- ATR | c.2101G>A p.D701N | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as rs1301785134, COSV100638736; called by muse, mutect2, varscan2
- AXIN2 | c.2432A>G p.E811G | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100197127; called by muse, mutect2
- BTRC | c.858G>A p.W286* (on ENST00000370187 / NM_033637.4; = p.W250* on NM_003939.5) | Nonsense Mutation (SNP) | VAF 10/168 reads (6%) | catalogued as COSV100927955; called by muse, mutect2
- C11orf53 | c.791T>A p.L264H | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99724952; called by muse, mutect2, varscan2
- C17orf98 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs762818252; called by muse, mutect2, varscan2
- CBARP | c.163G>A p.V55M (on ENST00000382477; = p.V61M on NM_152769.3) | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as rs1206465313, COSV99290026; called by muse, mutect2
- CDH11 | c.1460A>C p.K487T | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as COSV51759327, COSV51759358, COSV51764779; called by muse, mutect2, varscan2
- CEACAM5 | c.2056G>A p.G686R | Missense Mutation (SNP) | VAF 56/568 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as COSV99704237; called by muse, mutect2
- CLCN5 | c.1144A>C p.S382R | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV100260480; called by muse, mutect2, varscan2
- COL20A1 | c.2704G>A p.V902I | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.036); catalogued as rs755921135, COSV100491830; called by muse, mutect2, varscan2
- CPD | c.1475C>T p.S492F | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1357431098, COSV56712042; called by muse, mutect2, varscan2
- CSMD3 | c.7912C>T p.P2638S (on ENST00000297405 / NM_001363185.1; = p.P2534S on NM_052900.3) | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV52169683, COSV52233038, COSV99852242; called by muse, mutect2
- CTNNA2 | c.1402A>C p.T468P | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.611); catalogued as COSV100562453; called by muse, mutect2, varscan2
- DAB2IP | c.1627C>T p.P543S (on ENST00000408936; = p.P515S on NM_032552.3) | Missense Mutation (SNP) | VAF 10/161 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99406636; called by muse, mutect2
- DLGAP2 | c.1361C>T p.P454L | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1217084240, COSV70104264; called by muse, mutect2
- DNAH9 | c.8768A>C p.N2923T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.168); catalogued as COSV99309056; called by muse, mutect2, varscan2
- DOCK10 | c.6555A>C p.E2185D | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV99292414; called by muse, mutect2, varscan2
- DSEL | c.3641G>T p.R1214L | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV100026231; called by muse, mutect2, varscan2
- EPB41L3 | c.3213A>C p.K1071N | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59448617, COSV59460416; called by muse, mutect2, varscan2
- ERMARD | c.330A>G p.I110M | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as rs1432776838, COSV100824965; called by muse, mutect2, varscan2
- FGF12 | c.504A>T p.E168D (on ENST00000454309 / NM_021032.5; = p.E106D on NM_004113.6) | Missense Mutation (SNP) | VAF 17/308 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.023); catalogued as COSV99284580; called by muse, mutect2
- FGF13 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768293112, COSV100264529; called by muse, mutect2, varscan2
- GPAT3 | c.260G>T p.R87L | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.454); catalogued as COSV100023368; called by muse, mutect2
- GRIN2D | c.714T>G p.S238R | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.3); catalogued as COSV99617150; called by muse, mutect2
- GRM1 | c.745G>T p.A249S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.017); catalogued as COSV99269881; called by muse, mutect2, varscan2
- HEATR4 | c.871G>A p.V291I | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.137); catalogued as rs758423378, COSV100620663; called by muse, mutect2
- HERC1 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 63/227 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs544246854, COSV71250310; called by muse, mutect2, varscan2
- HIVEP2 | c.2269C>T p.R757C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as rs372948812; called by muse, mutect2, varscan2
- HTR7 | c.1286A>C p.E429A | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.197); catalogued as COSV53284478, COSV53289936; called by muse, mutect2, varscan2
- IDH1 | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 13/186 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV61629074; called by muse, mutect2
- KCNK9 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.153); catalogued as rs756601239, COSV57279846; called by muse, mutect2, varscan2
- KHDRBS2 | c.64G>T p.V22L | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV99838826; called by muse, mutect2, varscan2
- KHDRBS3 | c.849T>G p.S283R | Missense Mutation (SNP) | VAF 7/167 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.413); catalogued as COSV100879137; called by muse, mutect2
- KIAA0319L | c.2461G>A p.V821M | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100357861; called by muse, mutect2, varscan2
- KIAA1217 | c.3889G>A p.E1297K | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.048); catalogued as rs746635402, COSV100287522; called by muse, mutect2, varscan2
- KIAA1549L | c.202C>G p.L68V (on ENST00000321505; = p.L365V on NM_012194.3) | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.038); catalogued as COSV99684797; called by muse, mutect2
- KRT27 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 48/1276 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.059); catalogued as COSV100053414; called by muse, mutect2
- KRTAP1-1 | c.491G>T p.C164F | Missense Mutation (SNP) | VAF 202/229 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100092324; called by muse, mutect2, varscan2
- LAMA1 | c.3202A>C p.K1068Q | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.02); catalogued as COSV67532112, COSV67538011; called by muse, mutect2
- MAG | c.1681G>A p.D561N | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs201165241, COSV62701166; called by muse, mutect2, varscan2
- MAGEE2 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100973257, COSV64898197; called by muse, mutect2
- MAP2 | c.1145C>G p.A382G | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.122); catalogued as COSV99562173; called by muse, mutect2, varscan2
- MAT1A | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1038206403, COSV64745420; called by muse, mutect2, varscan2
- MICAL3 | c.4787G>A p.R1596H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs373879471; called by muse, mutect2, varscan2
- MPZL1 | c.248C>T p.T83I | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.068); catalogued as rs369996563; called by muse, mutect2, varscan2
- MUC16 | c.26896A>G p.T8966A | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.223); catalogued as COSV101202330; called by muse, mutect2, varscan2
- MUC16 | c.21031A>T p.R7011* | Nonsense Mutation (SNP) | VAF 56/181 reads (31%) | catalogued as COSV101202331; called by muse, mutect2, varscan2
- NCBP1 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100912713, COSV100912726; called by muse, mutect2
- NDN | c.851A>G p.K284R | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.253); catalogued as COSV59358784, COSV59359838; called by muse, mutect2, varscan2
- NEB | c.6288G>A p.M2096I | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT tolerated (1); PolyPhen possibly damaging (0.899); catalogued as COSV99429360; called by muse, mutect2
- NECTIN2 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.464); catalogued as rs777560306, COSV99375149; called by muse, mutect2, varscan2
- NFASC | c.2161C>T p.R721* (on ENST00000339876 / NM_001378329.1; = p.R717* on NM_015090.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 34/182 reads (19%) | catalogued as COSV58365582; called by muse, mutect2
- NOMO1 | c.2006T>C p.L669P | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.36); catalogued as rs967831662, COSV99814976; called by mutect2, varscan2
- OR14K1 | c.175T>G p.F59V | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99315575; called by muse, mutect2, varscan2
- OR1E1 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as COSV100492079; called by muse, mutect2
- OR5J2 | c.712T>G p.F238V | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56620520; called by muse, mutect2, varscan2
- PCDH15 | c.4841C>T p.T1614I (on ENST00000644397 / NM_001354429.2; = p.T1556I on NM_001142771.2) | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs771698332, COSV64678770; called by muse, mutect2, varscan2
- PCDH18 | c.1638A>C p.E546D | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.345); catalogued as COSV61268071; called by muse, mutect2, varscan2
- PCDHA3 | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.087); catalogued as rs781988680, COSV100793703; called by muse, varscan2
- PCLO | c.13437A>C p.Q4479H | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV100439705; called by muse, mutect2, varscan2
- PDGFRA | c.460G>T p.D154Y | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57268325, COSV99958062; called by muse, mutect2, varscan2
- PDZRN3 | c.2290T>G p.C764G | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99732996; called by muse, mutect2, varscan2
- PHEX | c.1225T>C p.F409L | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs754314481, COSV101040024; called by muse, mutect2, varscan2
- PHF14 | c.2409G>C p.Q803H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.528); catalogued as COSV101301883; called by muse, varscan2
- PI16 | c.551C>G p.S184C | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101028876; called by muse, mutect2
- PKN3 | c.2126-1G>A p.X709_splice | Splice Site (SNP) | VAF 19/332 reads (6%) | catalogued as COSV99404078; called by muse, mutect2
- PLXNA1 | c.886G>A p.V296I | Missense Mutation (SNP) | VAF 23/395 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs202007314, COSV52524105, COSV52526230; called by muse, mutect2
- PLXNC1 | c.2459C>T p.T820M | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs770962418, COSV99314174; called by muse, mutect2, varscan2
- POU3F3 | c.953C>T p.T318M | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63721896; called by muse, mutect2
- PRKDC | c.5576A>G p.N1859S | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.038); catalogued as COSV100043614; called by muse, mutect2
- PWWP3A | c.1405A>G p.K469E (on ENST00000627377; = p.K468E on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as COSV100262344; called by muse, mutect2, varscan2
- RBM41 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99179857; called by muse, mutect2
- RETSAT | c.1768C>T p.R590W | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs71337784; called by muse, mutect2, varscan2
- RHOV | c.377T>G p.L126R | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV99592160; called by muse, mutect2, varscan2
- RNF138 | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV99857734; called by muse, mutect2, varscan2
- ROBO2 | c.3373G>T p.D1125Y | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV59899737; called by muse, mutect2, varscan2
- RP1 | c.3790G>A p.V1264I | Missense Mutation (SNP) | VAF 18/203 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as rs1249682353, COSV99609345; called by muse, mutect2
- SCN9A | c.3812T>C p.V1271A (on ENST00000303354; = p.V1260A on NM_002977.3) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.532); catalogued as COSV100314723; called by muse, mutect2, varscan2
- SETD2 | c.5389C>T p.Q1797* | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as COSV57431960; called by muse, mutect2, varscan2
- SETMAR | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as rs746079872, COSV62780576; called by muse, mutect2, varscan2
- SLC17A6 | c.160G>C p.E54Q | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs890101292, COSV99582641; called by muse, mutect2, varscan2
- SLC6A7 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.274); catalogued as rs142379630; called by muse, mutect2, varscan2
- SPACA4 | c.209G>A p.S70N | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs1261873164; called by muse, mutect2, varscan2
- SPCS3 | c.37G>T p.A13S | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV101543717; called by muse, mutect2
- SPHK2 | c.1076C>T p.T359I | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as rs1323162709, COSV99709737; called by muse, mutect2
- SPTB | c.5560C>T p.Q1854* | Nonsense Mutation (SNP) | VAF 29/135 reads (21%) | catalogued as COSV101072507; called by muse, mutect2, varscan2
- SPTBN2 | c.3247C>T p.R1083C | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1427530674, COSV100020798; called by muse, mutect2
- ST6GAL2 | c.1583A>G p.H528R | Missense Mutation (SNP) | VAF 43/101 reads (43%) | PolyPhen benign (0); catalogued as COSV100699711; called by muse, mutect2, varscan2
- STXBP5 | c.2066G>A p.R689Q | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.382); catalogued as rs1160860099, COSV99471230; called by muse, mutect2
- TAFA5 | c.302C>T p.P101L (on ENST00000402357 / NM_001082967.3; = p.P94L on NM_015381.7) | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60971732; called by muse, mutect2
- TIAM2 | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59704621; called by muse, mutect2
- TNS4 | c.563G>C p.R188T | Missense Mutation (SNP) | VAF 30/830 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as rs764524983, COSV54183930, COSV99564261; called by muse, mutect2
- TRAF3 | c.1699G>A p.D567N | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as rs1292422642, COSV100693790; called by muse, mutect2
- TRAK1 | c.590G>A p.R197K (on ENST00000327628 / NM_001349247.2; = p.R139K on NM_014965.5) | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.87); PolyPhen benign (0.065); catalogued as COSV100410420; called by muse, mutect2, varscan2
- TTN | c.88711G>A p.E29571K (on ENST00000591111; = p.E22147K on NM_003319.4) | Missense Mutation (SNP) | VAF 14/43 reads (33%) | PolyPhen benign (0.436); catalogued as rs786205368, COSV100636298; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.24999T>A p.H8333Q (on ENST00000591111; = p.H7406Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/70 reads (46%) | PolyPhen benign (0); catalogued as rs372385679; called by muse, mutect2, varscan2
- UHRF1BP1L | c.1720C>T p.R574* | Nonsense Mutation (SNP) | VAF 22/71 reads (31%) | catalogued as rs776282417, COSV99692368; called by muse, mutect2, varscan2
- VARS1 | c.1270G>A p.G424S | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100989972; called by muse, mutect2, varscan2
- WDR36 | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as COSV101540842; called by muse, mutect2, varscan2
- ZC3H3 | c.1163C>T p.S388F | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99368851; called by muse, mutect2, varscan2
- ZNF578 | c.773_774del p.Q258Lfs*2 | Frame Shift Del (DEL) | VAF 18/90 reads (20%) | catalogued as rs1428297214; called by mutect2, pindel, varscan2
- ZNF592 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1365434101, COSV55436634; called by muse, mutect2, varscan2
- ZNF607 | c.876G>C p.Q292H | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.706); catalogued as COSV100777989; called by muse, mutect2, varscan2
- COX5B | c.266_268dup p.V89dup | In Frame Ins (INS) | VAF 14/168 reads (8%) | called by mutect2, pindel
- IFTAP | c.499-1_501del p.X167_splice | Splice Site (DEL) | VAF 5/35 reads (14%) | called by mutect2, pindel
- IGKV1D-43 | c.50T>A p.F17Y | Missense Mutation (SNP) | VAF 29/184 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- MUC6 | c.4598dup p.H1533Qfs*4 | Frame Shift Ins (INS) | VAF 61/276 reads (22%) | called by mutect2, pindel, varscan2
- SZT2 | c.7156_7157del p.I2386Hfs*28 (on ENST00000634258 / NM_001365999.1; = p.I2329Hfs*28 on NM_015284.4) | Frame Shift Del (DEL) | VAF 9/68 reads (13%) | called by mutect2, pindel, varscan2
- TJP2 | c.2848_2866del p.T950Cfs*7 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- TRGJP | c.19A>C p.K7Q | Missense Mutation (SNP) | VAF 48/153 reads (31%) | PolyPhen benign (0.079); called by muse, mutect2, varscan2
- UBE2NL | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.094); called by muse, mutect2
- ACSM2A | c.1008T>C p.T336= (on ENST00000219054; = p.T257= on NM_001308169.2) | Silent (SNP) | VAF 22/189 reads (12%) | catalogued as COSV99525858; called by muse, mutect2, varscan2
- ACTN2 | c.1347C>T p.S449= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs796733553, COSV100857132, COSV63972620; called by muse, mutect2, varscan2
- ASXL1 | c.2601G>A p.G867= | Silent (SNP) | VAF 42/221 reads (19%) | catalogued as COSV100041888, COSV60119685; called by muse, mutect2, varscan2
- CDYL2 | c.894G>T p.L298= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV73654894, COSV73655164; called by muse, mutect2, varscan2
- CFAP44 | c.1518C>T p.A506= | Silent (SNP) | VAF 28/254 reads (11%) | catalogued as COSV99870548; called by muse, mutect2, varscan2
- CNTN6 | c.2178A>G p.E726= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV100612109, COSV63190764; called by muse, mutect2, varscan2
- COL24A1 | c.552A>G p.K184= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV100994226; called by muse, mutect2, varscan2
- FGA | c.1455C>T p.S485= | Silent (SNP) | VAF 30/106 reads (28%) | catalogued as rs774171561, COSV57395341; called by muse, mutect2, varscan2
- GABRG1 | c.453A>G p.R151= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV99778981; called by muse, mutect2, varscan2
- GPR158 | c.2259C>A p.S753= | Silent (SNP) | VAF 14/184 reads (8%) | catalogued as COSV100894457; called by muse, mutect2
- GSTT2B | c.390G>A p.E130= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs1165064292, COSV99321073; called by mutect2, varscan2
- IGKV1-27 | c.15C>T p.V5= | Silent (SNP) | VAF 7/112 reads (6%) | catalogued as rs1224164507; called by muse, mutect2
- IPCEF1 | c.870C>A p.V290= | Silent (SNP) | VAF 23/92 reads (25%) | catalogued as rs960932436, COSV99500737; called by muse, mutect2, varscan2
- LDLRAD3 | c.738G>A p.A246= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as rs146712517; called by muse, mutect2, varscan2
- MAGEC1 | c.2892C>T p.S964= | Silent (SNP) | VAF 22/238 reads (9%) | catalogued as COSV53568562, COSV99595818; called by muse, mutect2
- MAS1L | c.603T>G p.P201= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV101009743; called by muse, mutect2, varscan2
- MORC1 | c.2868T>C p.L956= | Silent (SNP) | VAF 31/69 reads (45%) | catalogued as COSV99228290; called by muse, mutect2, varscan2
- MUC3A | c.8670G>A p.P2890= | Silent (SNP) | VAF 43/259 reads (17%) | catalogued as rs373990960; called by muse, mutect2, varscan2
- NENF | c.417C>T p.I139= | Silent (SNP) | VAF 6/117 reads (5%) | catalogued as rs1173915601, COSV100877110; called by muse, mutect2
- OR4C13 | c.117A>C p.G39= | Silent (SNP) | VAF 39/204 reads (19%) | catalogued as COSV101634254; called by muse, mutect2, varscan2
- PCDH15 | c.1734T>G p.T578= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as COSV57359628; called by muse, mutect2, varscan2
- PCDHB14 | c.2289G>A p.E763= | Silent (SNP) | VAF 9/121 reads (7%) | catalogued as rs781909873, COSV99506410; called by muse, mutect2
- PDGFRB | c.2484G>A p.A828= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs143342011; called by muse, mutect2, varscan2
- PLEC | c.12318G>A p.A4106= (on ENST00000322810 / NM_201380.4; = p.A3996= on NM_000445.5) | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as rs202099348, COSV100520187; ClinVar: likely benign; called by muse, mutect2
- PTCHD3 | c.1041C>T p.L347= | Silent (SNP) | VAF 41/269 reads (15%) | catalogued as rs1334226042, COSV71256873; called by muse, mutect2, varscan2
- RIN3 | c.2064G>A p.L688= | Silent (SNP) | VAF 33/424 reads (8%) | catalogued as COSV99380271; called by muse, mutect2
- SLC24A5 | c.636G>A p.L212= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV100165766; called by muse, mutect2, varscan2
- SPDEF | c.735C>T p.S245= | Silent (SNP) | VAF 108/223 reads (48%) | catalogued as rs200580057, COSV55059091; called by muse, mutect2, varscan2
- SPEN | c.7491G>A p.K2497= | Silent (SNP) | VAF 36/143 reads (25%) | catalogued as COSV101005768; called by muse, mutect2, varscan2
- SPOCK3 | c.345G>A p.R115= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as COSV100694336; called by muse, mutect2, varscan2
- SRPX2 | c.1104C>G p.T368= | Silent (SNP) | VAF 4/82 reads (5%) | catalogued as COSV100884072; called by muse, mutect2
- STARD13 | c.1872C>T p.L624= (on ENST00000336934 / NM_001243476.3; = p.L506= on NM_052851.3) | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV55236077; called by muse, mutect2, varscan2
- TDRD10 | c.531G>A p.R177= | Silent (SNP) | VAF 25/145 reads (17%) | catalogued as COSV99427779; called by muse, mutect2, varscan2
- THBS3 | c.1011C>T p.P337= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as rs1350504492; called by muse, mutect2
- TRIM48 | c.69A>G p.Q23= | Silent (SNP) | VAF 19/198 reads (10%) | catalogued as COSV101338206; called by muse, mutect2
- VPS72 | c.504C>A p.T168= | Silent (SNP) | VAF 42/207 reads (20%) | catalogued as COSV100614619; called by muse, mutect2, varscan2
- MIR182 | n.39C>T | RNA (SNP) | VAF 21/37 reads (57%) | called by muse, mutect2, varscan2
- MIR522 | n.29C>T | RNA (SNP) | VAF 33/140 reads (24%) | catalogued as rs765188254; called by muse, mutect2, varscan2
